CCDI case PBCHMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/f6223523-61c9-4621-9f79-0dd2f0a59f3f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Biospecimens (2 samples)
- Sample 0DS0ZF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS10B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
